Somatic mutation profile of tumor specimen TCGA-VN-A88L-01A (aliquot TCGA-VN-A88L-01A-11D-A34U-08) from TCGA case TCGA-VN-A88L, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 54.8 years (20,026 days).
Specimen TCGA-VN-A88L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25f9cc02-9c40-4e9a-a4dd-35129e8bac2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VN-A88L-10A (Blood Derived Normal), aliquot TCGA-VN-A88L-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e5dfa5e-e247-4a26-89b4-99fceb22d16d

The open-access MAF lists 20 somatic variants for this specimen: 10 protein-altering or splice-affecting, 10 silent.
By variant classification: Silent 10, Missense Mutation 7, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1G1 | c.1997C>T p.T666I | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV100249946; called by muse, mutect2
- ATP6V1C2 | c.1126C>T p.R376C (on ENST00000272238 / NM_001039362.2; = p.R330C on NM_144583.4) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs377277646; called by muse, mutect2, varscan2
- HHIP | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.991); catalogued as rs1294953362, COSV56838386, COSV99666394; called by muse, mutect2
- HYDIN | c.11305C>T p.R3769* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as rs746719490, COSV101124773; called by muse, mutect2, varscan2
- KMT5B | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV100069795, COSV58566064; called by muse, mutect2, varscan2
- OR2D2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143950338; called by muse, mutect2, varscan2
- RASD1 | c.332T>C p.F111S | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99245690; called by muse, mutect2
- RYR2 | c.11400T>C p.C3800= | Splice Region (SNP) | VAF 15/45 reads (33%) | catalogued as COSV100767165; called by muse, mutect2, varscan2
- SMTNL1 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1189340279, COSV67700403; called by muse, mutect2
- TNRC6B | c.4475T>G p.I1492S (on ENST00000454349 / NM_001162501.2; = p.I1382S on NM_015088.3) | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100108773; called by muse, mutect2
- ANK2 | c.5169A>G p.A1723= | Silent (SNP) | VAF 14/232 reads (6%) | catalogued as COSV99998892; called by muse, mutect2
- AP1G2 | c.402G>A p.E134= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV100436457; called by muse, mutect2
- CATSPER1 | c.1455C>T p.S485= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV100375511; called by muse, mutect2, varscan2
- DCAF10 | c.453C>G p.L151= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99647507; called by muse, mutect2
- ERICH3 | c.4365G>A p.Q1455= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV100443100; called by muse, mutect2
- GPR50 | c.1668C>T p.D556= | Silent (SNP) | VAF 43/76 reads (57%) | catalogued as rs747548013, COSV54441311; called by muse, mutect2, varscan2
- GRM1 | c.177C>T p.A59= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as rs951612592, COSV51395951; called by muse, mutect2
- HOXB3 | c.1167G>A p.A389= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs765721486, COSV57486536; called by muse, mutect2, varscan2
- MUC16 | c.17832C>T p.S5944= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as rs375728976; called by muse, mutect2
- SERPINA6 | c.672C>T p.D224= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs1324358512, COSV58583929; called by muse, mutect2, varscan2
